Gene-level copy-number profile of tumor specimen TCGA-B6-A0RE-01A from TCGA case TCGA-B6-A0RE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage X; Age at diagnosis: 61.5 years (22,449 days).
Specimen TCGA-B6-A0RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.268d0a2b-cd03-425f-8775-4202f6a2e339.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0RE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (3 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/102471c8-7e2b-4568-8c97-a9f1ba427b14

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 232; copy number 2: 22,653; copy number 3: 22,338; copy number 4: 7,106; copy number 5: 4,465; copy number 6: 2,310; copy number 7: 36; copy number 8: 73; copy number 9: 573; copy number 10: 11; copy number 16: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0RE-01A-11D-A059-01): tumor purity 0.64, ploidy 2.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:86,932,880–87,703,852, 5 genes (within-gene range 0–2): AC016987.2, AC016987.1, AC078905.1, AC020687.1, RNU6-185P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 696 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,996,754–42,897,290, 77 genes, copy number 8–10 (within-gene range 3–10) (broad region; genes not listed).
- chr10:44,712–29,409,366, 499 genes, copy number 9–16 (broad region; genes not listed).
- chr10:29,421,476–29,422,012, 1 gene, copy number 16: PTCHD3P1.
- chr12:3,077,355–3,286,564, 1 gene, copy number 7 (within-gene range 4–7): TSPAN9.
- chr12:3,149,797–3,593,973, 11 genes, copy number 7: TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, AC005865.2, LINC02827, LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155.
- chr12:3,610,307–3,612,003, 1 gene, copy number 7: AC005831.1.
- chr12:4,012,902–4,774,184, 21 genes, copy number 7 (within-gene range 4–7): AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1.
- chr12:5,032,388–5,092,742, 3 genes, copy number 8: AC005906.1, KCNA5, AC005906.3.
- chr12:5,948,877–6,914,241, 60 genes, copy number 9 (within-gene range 4–9): VWF, RN7SL69P, AC005845.1, CD9, Y_RNA, ATP5MFP5, PLEKHG6, TNFRSF1A, RN7SL391P, SCNN1A, LTBR, AC005840.2, AC005840.1, SRP14P1, CD27-AS1, CD27, TAPBPL, VAMP1, AC005840.4, AC005840.3, MRPL51, NCAPD2, SCARNA10, AC006064.5, AC006064.3, GAPDH, AC006064.4, IFFO1, AC006064.1, NOP2, AC006064.6, CHD4, AC006064.2, SCARNA11, LPAR5, ACRBP, ING4, AC125494.1, ZNF384, PIANP, RNU6-781P, AC125494.3, COPS7A, AC125494.2, MLF2, PTMS, LAG3, RN7SL380P, CD4, GPR162, P3H3, GNB3, CDCA3, USP5, TPI1, SPSB2, RPL13P5, LRRC23, DSTNP2, U47924.3.
- chr12:7,689,784–7,936,187, 16 genes, copy number 9: GDF3, DPPA3, CLEC4C, NANOGNB, Y_RNA, NANOG, Y_RNA, SLC2A14, AC006517.2, Y_RNA, Metazoa_SRP, AC006517.1, AC124891.1, NANOGP1, AC007536.1, SLC2A3.
- chr12:11,548,030–12,211,084, 5 genes, copy number 7–8 (within-gene range 4–8): LINC01252, ETV6, BCL2L14, PTMAP9, MIR1244-4.
- chr12:12,155,262–12,155,772, 1 gene, copy number 8: AC007537.1.

Autosomal genes at a single copy (total copy number 1): 232. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
